Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017976-09A.1 (aliquot TARGET-15-SJMPAL017976-09A.1-01D) from TARGET case TARGET-15-SJMPAL017976, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,022 days).
Specimen TARGET-15-SJMPAL017976-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca6c39fe-920f-4df7-8d65-92bf7512ef8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017976-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017976-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9f97355-40d9-4fd7-b00e-ce04dd075e15

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 6, Silent 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | catalogued as rs397515401, CM122406, COSV60107754, COSV60115393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4306G>T p.E1436* (on ENST00000358273 / NM_001042492.3; = p.E1415* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as rs876660428, CM000804, COSV62209826; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 81/205 reads (40%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- DBH | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs781667738; called by muse, mutect2, varscan2
- IPO7 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV65684130; called by muse, mutect2, varscan2
- KALRN | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.997); catalogued as rs367667422; called by muse, mutect2, varscan2
- OR7C2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs1197723389; called by muse, mutect2, varscan2
- PLXNA4 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs753325197, COSV58127821; called by muse, mutect2, varscan2
- SMURF1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs371859465, COSV63157556, COSV63159073; called by muse, varscan2
- TAF4 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376636061; called by muse, mutect2, varscan2
- TMEM130 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.106); catalogued as COSV59557727; called by muse, mutect2
- WT1 | c.1101_1102insGGGGC p.R368Gfs*71 | Frame Shift Ins (INS) | VAF 94/224 reads (42%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by pindel, varscan2
- WT1 | c.1069delinsGG p.R357Gfs*16 | Frame Shift Ins (INS) | VAF 47/192 reads (24%) | catalogued as CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; called by pindel, varscan2*
- DPY19L4 | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FBXO11 | c.593G>T p.R198L (on ENST00000403359 / NM_001190274.2; = p.R114L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.572); called by muse, mutect2
- MED16 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.581); called by muse, mutect2
- NTNG2 | c.1314C>A p.C438* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- PTGES | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.7573A>T p.K2525* | Nonsense Mutation (SNP) | VAF 69/80 reads (86%) | called by muse, mutect2, varscan2
- SLC26A8 | c.494G>T p.S165I | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- SLC4A8 | c.1905C>A p.Y635* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- MGAM | c.1917C>A p.S639= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV72075290; called by muse, mutect2
- UHRF1BP1L | c.882G>T p.T294= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV54441354; called by muse, mutect2
- VKORC1 | c.173+130A>G | Intron (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
